Somatic mutation profile of tumor specimen 0DMKL4 from CCDI case PBBVYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,386 days).
Specimen 0DMKL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8686d5cc-9118-40df-aed9-149a32f06f05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4574f425-5733-43b8-9017-0fa0631b6963

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF15 | c.1132A>T p.N378Y | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs768325182; called by muse, varscan2
- ARVCF | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs1186218913; called by muse, mutect2, varscan2
- BX276092.9 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1031595281; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 209/1239 reads (17%) | catalogued as rs547340067, COSV71672032; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- ARHGEF15 | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, varscan2
- MAPKAPK5 | c.1100+1G>A p.X367_splice | Splice Site (SNP) | VAF 160/489 reads (33%) | called by muse, mutect2, varscan2
- RNF183 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- TESC | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, varscan2
- ZNF574 | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2
- NEURL4 | c.1113T>C p.V371= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, varscan2
- NXPH4 | c.798C>G p.A266= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- SLC9A2 | c.1299C>A p.A433= | Silent (SNP) | VAF 67/1576 reads (4%) | called by muse, mutect2
- KCTD1 | c.-15-47232A>G | Intron (SNP) | VAF 10/115 reads (9%) | catalogued as rs1239762396; called by muse, mutect2
- MAP3K6 | c.-60_-59insCGGCTCAGCGCCACGGCCAGCGGGTCCTGCCAGCAGCTGCCGGCCC | 5'UTR (INS) | VAF 0/8 reads (0%) | called by mutect2, varscan2*
- PARD6G | c.*97A>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs943151572, COSV62062381; called by muse, varscan2
- PPP2R2D | c.-27T>C | 5'UTR (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- SLC22A31 | c.*54A>C | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by mutect2, varscan2
